Somatic mutation profile of tumor specimen TCGA-EL-A3T6-01A (aliquot TCGA-EL-A3T6-01A-11D-A21Z-08) from TCGA case TCGA-EL-A3T6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.0 years (12,777 days).
Specimen TCGA-EL-A3T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eed25055-e739-49d2-9f4e-6d00dfd8b410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T6-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T6-11A-11D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c459f3c8-4c79-4f06-af79-04c3f22579dd

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADARB1 | c.1860G>C p.L620F (on ENST00000360697 / NM_001346687.2; = p.L580F on NM_001112.4) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as COSV62348913; called by muse, mutect2, varscan2
- DCAF12 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63514141; called by muse, mutect2
- DYNC1H1 | c.4074+1G>T p.X1358_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV64140457, COSV64143860; called by muse, mutect2
- USH2A | c.3040T>C p.C1014R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56450121; called by muse, mutect2, varscan2
- PRDM8 | c.1941C>T p.H647= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV60205316; called by muse, mutect2, varscan2
